Surgical pathology report (de-identified scan), TCGA case TCGA-21-1082, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1082-01A (Primary Tumor).

[page 1 of 4]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

A: CYTOLOGY

B: L11 LYMPH NODES

C: CYTOLOGY

D: LEFT LOWER LOBE

E: BRONCHIAL L11 NODES

F: NODE @ RESECTION MARGIN

G: LEVEL 7 LN

H: PULMONARY ARTERY LEVEL 5 LN

Gross Description:

GROSS DESCRIPTION: Received in eight parts.

SOURCE OF TISSUE: 1. CYTOLOGY

SOURCE OF TISSUE: 2. Labeled #2, "L11 lymph nodes"..

GROSS DESCRIPTION: Received fresh are three gray-black, anthracotic-stained tissue fragments, 0.4 to 0.8 cm. in greatest dimension. They are submitted in toto in one block.

DESIGNATION OF SECTIONS: Block 2

SUMMARY OF SECTIONS: undesignated-3

SOURCE OF TISSUE: 3. CYTOLOGY

SOURCE OF TISSUE: 4. Labeled #4, "left lower lobe".

FROZEN SECTION DIAGNOSIS: 4FSA-4FSB - RESERVE CELL HYPERPLASIA. NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 235 gram, 12.5 x 10.5 x 4.5 cm. left lower lobectomy of lung. It is covered by a pink to red-purple, focally anthracotic-stained pleura. There is up to 0.6 cm. of attached bronchus. The bronchial resection margin is entirely submitted for frozen section evaluation and the frozen section residues are submitted in two blocks. In the anterior segment, there is a 1.5 cm. in greatest dimension area where the pleura is umbilicated. On sectioning through this area, there is an underlying 5.0 x 4.5 x 3.2 cm. firm mass. The cut surfaces are light tan, firm, having irregular borders. The mass extends to the hilar structures surrounding the bronchus and vessels. The

[page 2 of 4]
remaining cut surfaces of the lung range from being tan-pink, soft and crepitant to areas which are red-purple and soft. There are few palpable hilar lymph nodes, 0.4 cm. in greatest dimension. Each is gray-black and anthracotic- stained. A representative section of each lymph node is submitted. Representative sections are submitted in eight blocks.

DESIGNATION OF SECTIONS: 4FSA-4FSB - frozen section bronchial resection margin, 4A - vascular resection margin, 4B-4C - tumor with inked pleural surface, 4D-4F - random tumor sections, 4G - random sections of uninvolved lung, 4H - hilar lymph nodes,

SUMMARY OF SECTIONS: 4FSA-1, 4FSB-1, 4A-3, 4B-1, 4C-1, 4D-1, 4E-1, 4F-1, 4G-2, 4H-4

SOURCE OF TISSUE: 5. Labeled #5, "bronchial L11 nodes".

FROZEN SECTION DIAGNOSIS: 5FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation are three gray-black, anthracotic-stained tissue fragments, 0.6 to 1.4 cm. in greatest dimension. They are submitted in toto for frozen section reevaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 5FS

SUMMARY OF SECTIONS: 5FS-3

*

SOURCE OF TISSUE: 6. Labeled #6, "node at resection margin".

FROZEN SECTION DIAGNOSIS: 6FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation are two gray-black, anthracotic-stained tissue fragments, 0.4 and 1.0 cm. in greatest dimension. They are submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 6FS

SUMMARY OF SECTIONS: 6FS-2

SOURCE OF TISSUE: 7. Labeled #7, "level 7 lymph node".

FROZEN SECTION DIAGNOSIS: 7FS - NO TUMOR SEEN.

[page 3 of 4]
GROSS DESCRIPTION: Received fresh for frozen section evaluation are two tan to gray-black, anthracotic-stained tissue fragments, 1.0 and 1.2 cm. in greatest dimension. They are submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 7FS

SUMMARY OF SECTIONS: 7FS-2

SOURCE OF TISSUE: 8. Labeled #8, "PA level 5 lymph node".

FROZEN SECTION DIAGNOSIS; 8FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 0.8 cm. gray-black, anthracotic-stained tissue fragment which is submitted in toto for frozen section evaluation. The frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 8FS

SUMMARY OF SECTIONS: 8FS-1

Final Diagnosis:

DIAGNOSIS:

1. CYTOLOGY

2. L11 LYMPH NODES:

- THREE LYMPH NODES ALL NEGATIVE FOR TUMOR (0/3).

3. CYTOLOGY

4. LEFT LOWER LOBE:

- SQUAMOUS CELL CARCINOMA, NONKERATINIZING, POORLY DIFFERENTIATED, 5.0 CM.

- TUMOR FOCALLY EXTENDS INTO BUT NOT THROUGH THE PLEURA.

- BRONCHIAL AND VASCULAR RESECTION MARGINS ARE NEGATIVE FOR TUMOR.

- THREE PERIBRONCHIAL LYMPH NODES ARE NEGATIVE FOR TUMOR (0/3).

5. BRONCHIAL L11 LYMPH NODES:

- FOUR LYMPH NODES ALL NEGATIVE FOR TUMOR (0/4).

6. LYMPH NODE AT RESECTION MARGIN:

- LYMPH NODE NEGATIVE FOR TUMOR (0/1).

- MARGIN NEGATIVE FOR TUMOR.

[page 4 of 4]
7. LEVEL 7 LYMPH NODE:

- TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2).

8. PULMONARY ARTERY LEVEL 5 LYMPH NO:

- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).

SYNOPTIC REPORT FOR LUNG CANCER

A NEOPLASM IS PRESENT

LOCATION OF TUMOR: LEFT LOWER LOBE

THE HISTOLOGIC CLASSIFICATION OF THE TUMOR IS SQUAMOUS CELL
(EPIDERMOID)

CARCINOMA, NON-KERATINIZING TYPE

THE GRADE OF THE TUMOR IS: ; POORLY DIFFERENTIATED (GRADE III)

LYMPHATIC INVASION BY TUMOR IS ABSENT

VENOUS INVASION BY TUMOR IS ABSENT

ARTERIAL INVASION BY TUMOR IS ABSENT

INVASION INTO BUT NOT THROUGH THE PLEURA BY TUMOR IS PRESENT

INVASION THROUGH THE PLEURA BY TUMOR IS ABSENT

TUMOR NECROSIS IS MODERATE

THE SURGICAL MARGINS ARE UNINVOLVED BY TUMOR

THE NON-NEOPLASTIC LUNG TISSUE SHOWS EMPHYSEMA

LYMPH NODES DEMONSTRATE NO EXTRACAPSULAR EXTENSION OF TUMOR

THE TOTAL NUMBER OF NODES EXAMINED IS: 11

THE TOTAL NUMBER OF POSITIVE NODES IS: 0

STAGING

T2

N0

Source: NCI Genomic Data Commons file 3de4163f-bc08-4497-a7dc-2c50034a065f (TCGA-21-1082.C5B2CA19-E38D-41F2-9530-65A610990954.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).